Somatic mutation profile of tumor specimen TCGA-ZF-A9R7-01A (aliquot TCGA-ZF-A9R7-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9R7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 76.8 years (28,063 days).
Specimen TCGA-ZF-A9R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9de89786-01ff-451b-9c4e-70868096a576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R7-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R7-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6051eb5a-c106-49ce-a3ba-e73a42617bd0

The open-access MAF lists 783 somatic variants for this specimen: 575 protein-altering or splice-affecting, 186 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 503, Silent 186, Nonsense Mutation 56, Intron 13, Splice Site 7, Splice Region 5, RNA 4, 5'Flank 3, Translation Start Site 2, 5'UTR 2, Frame Shift Del 1, Nonstop Mutation 1.

Variants (750 of 783; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- COL3A1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as rs1057521106, CM151297, COSV58583434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2301C>G p.I767M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54064925; called by muse, mutect2, varscan2
- GRIN2B | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs774592932, COSV101663078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PNLIP | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746000327, CM141074, COSV65039918, COSV65040496; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs370456693; called by muse, mutect2, varscan2
- ABCC5 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV55588236, COSV55593054; called by muse, mutect2, varscan2
- ABLIM3 | c.1860C>G p.I620M | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV58645488; called by muse, mutect2, varscan2
- ACSM2A | c.1219G>A p.E407K (on ENST00000219054; = p.E328K on NM_001308169.2) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV54586809; called by muse, mutect2, varscan2
- ACTL7B | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1243349202, COSV65927690; called by muse, mutect2, varscan2
- ACTR1A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs568740960, COSV64023673; called by muse, mutect2, varscan2
- ACTRT2 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101007648, COSV65759783; called by muse, mutect2, varscan2
- ADAM11 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.544); catalogued as COSV52347765; called by muse, mutect2, varscan2
- ADAM32 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65951316; called by muse, mutect2
- ADAMTS2 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV52382438; called by muse, mutect2, varscan2
- ADAT1 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57186409; called by muse, mutect2, varscan2
- ADGRG4 | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV54961155; called by muse, mutect2, varscan2
- ADGRG4 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770354001, COSV54961164; called by muse, mutect2, varscan2
- ADPGK | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61174489, COSV99076611; called by muse, mutect2, varscan2
- AGR3 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60038685; called by muse, mutect2
- AKNA | c.2844C>G p.I948M | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV56311589, COSV56313679; called by muse, mutect2, varscan2
- AKT2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1319165364, COSV60909183; called by muse, mutect2, varscan2
- AKT3 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1210004922, COSV55622857; called by muse, mutect2, varscan2
- ALX1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV57493127; called by muse, mutect2, varscan2
- ALYREF | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV58668773; called by muse, mutect2, varscan2
- AMFR | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV51922773; called by muse, mutect2, varscan2
- AMOT | c.1723C>T p.R575* (on ENST00000371959 / NM_001113490.1; = p.R166* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 13/207 reads (6%) | catalogued as rs1325679862, COSV100495544, COSV59064016; called by muse, mutect2
- ANKRD12 | c.4444C>A p.P1482T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV50834079; called by muse, mutect2, varscan2
- ANKS1A | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV64461182, COSV64462203; called by muse, mutect2, varscan2
- ANO5 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV61087484; called by muse, mutect2
- ANO9 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV60450268; called by muse, mutect2, varscan2
- ANOS1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as CM133693, COSV99390997; called by muse, mutect2, varscan2
- APOB | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs756379920, COSV51942735; called by muse, mutect2, varscan2
- AQR | c.4025G>C p.R1342T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV50037991, COSV50040348; called by muse, mutect2, varscan2
- AQR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50040393; called by muse, mutect2, varscan2
- ARHGAP17 | c.2545C>T p.R849C (on ENST00000289968 / NM_001006634.3; = p.R771C on NM_018054.6) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs772552729, COSV51509512; called by muse, mutect2, varscan2
- ARHGAP9 | c.1804G>A p.D602N (on ENST00000393797 / NM_001319850.2; = p.D583N on NM_032496.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57364359; called by muse, mutect2, varscan2
- ARHGEF10L | c.1595C>G p.S532* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV99393094; called by muse, mutect2, varscan2
- ARHGEF18 | c.325C>G p.Q109E (on ENST00000359920 / NM_001130955.2; = p.Q5E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV60471471; called by muse, mutect2, varscan2
- ARID1A | c.2489G>C p.G830A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV61382258; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARID1B | c.5709C>G p.I1903M | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV51669605; called by muse, mutect2, varscan2
- ARPC4 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV55028982; called by muse, mutect2, varscan2
- ARPP21 | c.2320C>G p.Q774E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51802133; called by muse, mutect2, varscan2
- ASAP2 | c.2685-1G>C p.X895_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV55634548; called by muse, mutect2, varscan2
- ASCC3 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs746929248, COSV61230838; called by muse, mutect2, varscan2
- ATL3 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV60297088; called by muse, mutect2, varscan2
- ATN1 | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs1555144215, COSV100755829, COSV63110361; called by muse, mutect2, varscan2
- ATP12A | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV54519233; called by muse, mutect2, varscan2
- ATP6V1G3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV55278229; called by muse, mutect2, varscan2
- AZIN2 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs777803401, COSV53858769; called by muse, mutect2, varscan2
- B3GAT1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1451695136, COSV56998935; called by mutect2, varscan2
- B4GAT1 | c.33C>G p.F11L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as rs1384254410, COSV100240301; called by muse, mutect2, varscan2
- BBS2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV55327381; called by muse, mutect2, varscan2
- BCLAF3 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 64/167 reads (38%) | catalogued as COSV100503327; called by muse, mutect2, varscan2
- BCLAF3 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as COSV100503328; called by muse, mutect2, varscan2
- BEND4 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs867333263, COSV72469113; called by muse, mutect2, varscan2
- BGLAP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1204908084, COSV52745846; called by muse, mutect2, varscan2
- BNC1 | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61758229; called by muse, mutect2, varscan2
- BRAP | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as COSV100554180; called by muse, mutect2, varscan2
- BROX | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs939085791, COSV61799535, COSV61799878; called by muse, mutect2, varscan2
- BSDC1 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as rs1319084553, COSV61982127; called by muse, mutect2, varscan2
- BTG1 | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55459562; called by muse, mutect2, varscan2
- BVES | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58948767; called by muse, mutect2, varscan2
- C1QTNF5 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as COSV60990948; called by muse, mutect2, varscan2
- C1orf216 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754176327, COSV52053590; called by muse, mutect2, varscan2
- C2orf16 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs760249946, COSV62676838; called by muse, mutect2, varscan2
- C9orf72 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.641); catalogued as COSV66163671; called by muse, mutect2, varscan2
- CACNA1E | c.3367A>G p.T1123A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV62404676; called by muse, mutect2, varscan2
- CALCRL | c.1228T>C p.F410L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV66476009; called by muse, mutect2, varscan2
- CAMK1 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV56539467; called by muse, mutect2, varscan2
- CAMK2D | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.872); catalogued as COSV56434476; called by muse, mutect2, varscan2
- CARF | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV57548584; called by muse, mutect2, varscan2
- CARF | c.558-1G>T p.X186_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV57548592; called by muse, mutect2, varscan2
- CASP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV62057008; called by muse, mutect2, varscan2
- CAVIN2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as rs765261157, COSV58424796; called by muse, mutect2, varscan2
- CBFA2T2 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV60074747; called by muse, mutect2, varscan2
- CBLB | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51430884; called by muse, varscan2
- CC2D2B | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV60357403; called by muse, mutect2, varscan2
- CCAR1 | c.1895C>G p.S632C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV56271492; called by muse, mutect2, varscan2
- CCDC113 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV54686794; called by muse, mutect2, varscan2
- CCDC30 | c.1732G>C p.D578H (on ENST00000340612; = p.D535H on NM_001080850.3) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs1424195395, COSV59607805; called by muse, mutect2, varscan2
- CCDC40 | c.3238G>C p.E1080Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV100163009, COSV56409805; called by muse, mutect2, varscan2
- CCDC88A | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745518858, COSV55057245; called by muse, mutect2, varscan2
- CCR6 | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV59475633; called by muse, mutect2, varscan2
- CD300LD | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV60084197; called by muse, mutect2, varscan2
- CDA | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100906273, COSV100906334; called by muse, mutect2, varscan2
- CDCA2 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57946991; called by muse, mutect2, varscan2
- CDH17 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV50332450, COSV50337690; called by muse, mutect2, varscan2
- CDK12 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754901174, COSV71000245, COSV71001575; called by muse, mutect2, varscan2
- CDKN1A | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55190047; called by muse, varscan2
- CEP250 | c.3823G>C p.D1275H | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV61171725; called by muse, mutect2, varscan2
- CEP350 | c.8467G>A p.D2823N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62605642; called by muse, mutect2, varscan2
- CEP85 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs369652785; called by muse, mutect2, varscan2
- CEP85 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as COSV99432454; called by muse, mutect2, varscan2
- CERS5 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs147527651; called by muse, mutect2, varscan2
- CFAP94 | c.1476G>C p.L492F (on ENST00000320267 / NM_001352064.2; = p.L498F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV57234139; called by muse, mutect2, varscan2
- CFHR4 | c.1583A>T p.Q528L (on ENST00000367416 / NM_001201551.2; = p.Q282L on NM_006684.5) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV52231771, COSV52233719; called by muse, mutect2, varscan2
- CHD3 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV57877456; called by muse, mutect2, varscan2
- CHD4 | c.3424C>G p.Q1142E (on ENST00000357008 / NM_001363606.2; = p.Q1155E on NM_001273.5) | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58905061; called by muse, mutect2, varscan2
- CHGB | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66761010; called by muse, mutect2, varscan2
- CHL1 | c.2205G>C p.L735F (on ENST00000397491 / NM_001253387.1; = p.L751F on NM_006614.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56608128, COSV99851496; called by muse, mutect2
- CIB1 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767933367, COSV60174570; called by muse, mutect2, varscan2
- CLEC16A | c.2910G>C p.R970S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV55490547; called by muse, mutect2, varscan2
- CLEC1A | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59532942; called by muse, mutect2, varscan2
- CLNS1A | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV54440474; called by muse, mutect2
- CLUL1 | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV58112655; called by muse, varscan2
- CNTLN | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1169565271, COSV52085883; called by muse, mutect2, varscan2
- CNTN6 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.893); catalogued as rs1224609850, COSV63179285; called by muse, mutect2, varscan2
- CNTNAP2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV62214391; called by muse, mutect2, varscan2
- CNTNAP2 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100672540, COSV62185665; called by muse, mutect2, varscan2
- COASY | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV55899474; called by muse, mutect2
- COG2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as COSV100794595, COSV64187464; called by muse, mutect2
- COL14A1 | c.1841C>G p.P614R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.999); catalogued as COSV52860441; called by muse, mutect2, varscan2
- COL3A1 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58592705; called by muse, mutect2, varscan2
- COL5A2 | c.4299C>G p.I1433M | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV66411509; called by muse, mutect2
- COL6A6 | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as COSV62030155; called by muse, mutect2, varscan2
- COL7A1 | c.6040C>T p.Q2014* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100096632; called by muse, mutect2, varscan2
- COLQ | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV67524277, COSV67525299; called by muse, mutect2, varscan2
- CR1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.69); catalogued as COSV65456666, COSV65459135, COSV65460002; called by muse, mutect2
- CRELD2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV60304271; called by muse, mutect2, varscan2
- CSPP1 | c.862G>A p.E288K (on ENST00000676605; = p.E247K on NM_024790.6) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV51587860; called by muse, mutect2, varscan2
- CTTNBP2 | c.2732G>C p.R911T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV50419590, COSV99353714; called by muse, mutect2, varscan2
- CUBN | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 41/150 reads (27%) | catalogued as COSV100912907, COSV64728294; called by muse, mutect2, varscan2
- CUL9 | c.6729C>G p.I2243M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279994272; called by muse, mutect2
- CXCR4 | c.928A>G p.K310E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV54014194; called by muse, mutect2, varscan2
- CXorf38 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100010428; called by muse, mutect2, varscan2
- CYLC2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1258983342, COSV66336498, COSV66338357; called by muse, mutect2, varscan2
- CYSLTR2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.019); catalogued as COSV56166415; called by muse, mutect2, varscan2
- CYYR1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as rs761808985, COSV54834620; called by muse, mutect2, varscan2
- DAW1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs1295962456, COSV59367079; called by muse, mutect2, varscan2
- DDB2 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs748644904, COSV57039682; called by muse, mutect2, varscan2
- DDX18 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs778782995, COSV54306284; called by muse, mutect2, varscan2
- DDX42 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV63790643; called by muse, mutect2, varscan2
- DDX43 | c.1739G>C p.R580T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64813226; called by muse, mutect2, varscan2
- DDX5 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV56750176, COSV56751533; called by muse, mutect2, varscan2
- DGKK | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65708429; called by muse, mutect2, varscan2
- DHX29 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.057); catalogued as COSV52419459; called by muse, mutect2, varscan2
- DHX37 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs202185570, COSV58136564; called by muse, mutect2, varscan2
- DIP2B | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1197391315, COSV56587434, COSV56594210; called by muse, mutect2
- DISC1 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV54412085; called by muse, mutect2
- DISC1 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV100790453; called by muse, mutect2
- DISP2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs760255017, COSV51128449; called by muse, mutect2, varscan2
- DISP3 | c.1267del p.Q423Rfs*96 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as COSV53831552; called by mutect2, pindel, varscan2
- DLG3 | c.1146-1G>A p.X382_splice (on ENST00000374360 / NM_021120.4; = p.X45_splice on NM_020730.3) | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52084568; called by muse, mutect2, varscan2
- DNAJC10 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV51141666, COSV99898903; called by muse, mutect2, varscan2
- DOCK3 | c.2683G>A p.D895N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56533400; called by muse, mutect2, varscan2
- DOCK4 | c.4702G>C p.D1568H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1442809108, COSV70239858; called by muse, mutect2, varscan2
- DOCK7 | c.6043C>G p.P2015A (on ENST00000635253 / NM_001367561.1; = p.P1984A on NM_033407.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52012681; called by muse, mutect2, varscan2
- DOCK9 | c.3796G>A p.E1266K (on ENST00000376460 / NM_001366676.2; = p.E1267K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV59635437; called by muse, mutect2, varscan2
- DOK1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV51207488, COSV51216457, COSV99284105; called by muse, mutect2
- DOK7 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as rs772577244, COSV60773003; called by muse, mutect2, varscan2
- DOP1B | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as COSV67694247; called by muse, mutect2, varscan2
- DOT1L | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as COSV67111273; called by muse, mutect2, varscan2
- DSG1 | c.1199C>G p.S400* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV57134499, COSV99936140; called by muse, mutect2, varscan2
- DST | c.20598G>C p.K6866N (on ENST00000361203 / NM_001374722.1; = p.K4563N on NM_015548.5) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55025287; called by muse, mutect2, varscan2
- DTX3L | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1386428423, COSV56144842; called by muse, mutect2, varscan2
- DTX3L | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56144851; called by muse, mutect2, varscan2
- DTX3L | c.1122G>C p.M374I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV56144864, COSV99950041; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.923G>C p.R308T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50052150; called by muse, mutect2, varscan2
- DYNC1I1 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61455510; called by muse, mutect2, varscan2
- EEF1A2 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); catalogued as COSV53207042, COSV99419357; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as COSV62568905; called by muse, mutect2, varscan2
- ELAPOR1 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV64040747; called by muse, mutect2, varscan2
- ELAPOR1 | c.1725C>G p.I575M | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64040750; called by muse, mutect2, varscan2
- ELAVL1 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100688391; called by muse, mutect2, varscan2
- ELAVL4 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63914145, COSV63917460; called by muse, mutect2, varscan2
- ELF3 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62839293; called by muse, mutect2, varscan2
- EME1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56812879, COSV56813131; called by muse, mutect2, varscan2
- EMID1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV61830065; called by muse, mutect2, varscan2
- EPB41 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV58050253, COSV58051606; called by muse, mutect2, varscan2
- EPB41L1 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1293388673, COSV52440419; called by muse, mutect2, varscan2
- EPB41L2 | c.2044-1G>C p.X682_splice | Splice Site (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100441673, COSV61357096; called by muse, mutect2, varscan2
- EPB41L3 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV59459979; called by muse, mutect2, varscan2
- EPB41L4B | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV65803984; called by muse, mutect2, varscan2
- EPCAM | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.398); catalogued as COSV55393678; called by muse, mutect2, varscan2
- EPHA3 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60714547; called by muse, varscan2
- EPHA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs369606981, COSV56635227; called by muse, mutect2, varscan2
- EXOSC8 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753450309, COSV53509612; called by muse, mutect2, varscan2
- F11 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV53008051; called by muse, mutect2, varscan2
- F8 | c.5926C>A p.H1976N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM123983, COSV64275762; called by muse, mutect2, varscan2
- FAM110A | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.705); catalogued as rs768910329, COSV55727557; called by muse, mutect2, varscan2
- FAM135B | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV52737945; called by muse, mutect2, varscan2
- FAM217A | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV51161009; called by muse, mutect2, varscan2
- FAM3D | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV62558761; called by muse, mutect2, varscan2
- FAM47A | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 30/126 reads (24%) | catalogued as COSV60495784; called by muse, mutect2, varscan2
- FAM90A1 | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | catalogued as COSV100274359; called by muse, mutect2, varscan2
- FAT4 | c.10442C>A p.S3481* | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as COSV100628988; called by muse, mutect2, varscan2
- FBN2 | c.5080G>C p.D1694H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52526928; called by muse, mutect2, varscan2
- FBXW7 | c.1195G>C p.D399H (on ENST00000281708 / NM_001349798.2; = p.D319H on NM_018315.5) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55932843, COSV99654487; called by muse, mutect2, varscan2
- FDX1 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs1170675747, COSV52800162; called by muse, mutect2, varscan2
- FEZF2 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1458908981, COSV51863958, COSV51864284; called by muse, mutect2
- FLII | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.578); catalogued as COSV100375755, COSV57499184; called by muse, mutect2, varscan2
- FN1 | c.6424G>A p.D2142N (on ENST00000359671 / NM_001365524.2; = p.D2111N on NM_002026.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.95); catalogued as COSV60557549; called by muse, mutect2, varscan2
- FOXG1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as COSV57395888; called by muse, mutect2, varscan2
- FOXO3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100669942; called by muse, mutect2
- FOXO3 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1198837909, COSV59629453; called by muse, varscan2
- FOXO3 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV59629458; called by muse, varscan2
- FOXO3 | c.1763C>G p.S588* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100669951; called by muse, mutect2, varscan2
- FRAS1 | c.5581G>C p.D1861H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53625599; called by muse, mutect2, varscan2
- FREM2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.197); catalogued as COSV54843475; called by muse, mutect2, varscan2
- FRMPD2 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1463259044, COSV59720171; called by muse, varscan2
- FRY | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66573762; called by muse, mutect2
- FSTL1 | c.695-1G>C p.X232_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV55234770; called by muse, mutect2, varscan2
- FSTL5 | c.2529G>T p.W843C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60208660; called by muse, mutect2, varscan2
- GABRA2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs1196674223, COSV62916644; called by muse, mutect2, varscan2
- GARS1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV66828772; called by muse, mutect2, varscan2
- GATA3 | c.243G>T p.G81= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60520412; called by muse, mutect2, varscan2
- GATA3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs770601456, CD071349, COSV60519188, COSV60520419; called by muse, mutect2, varscan2
- GCM2 | c.963G>C p.E321D | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.108); catalogued as COSV65276049; called by muse, mutect2, varscan2
- GCN1 | c.2246C>A p.S749Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100326172, COSV56110687; called by muse, mutect2, varscan2
- GCN1 | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV56110697; called by muse, mutect2, varscan2
- GIMAP6 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV100188247, COSV61034031; called by muse, mutect2, varscan2
- GINM1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100805347; called by muse, mutect2, varscan2
- GLRB | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV52419302; called by muse, mutect2, varscan2
- GNB1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66100096; called by muse, mutect2
- GNGT2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV55930177; called by muse, mutect2, varscan2
- GNL3L | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV60577034; called by muse, mutect2, varscan2
- GOLGB1 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1466011464, COSV61467824; called by muse, varscan2
- GP6 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV100117589; called by muse, mutect2
- GPC6 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1359947479, COSV65520855; called by muse, mutect2, varscan2
- GPRASP2 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV59991924; called by mutect2, varscan2
- GREM2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58949432, COSV58953712; called by muse, mutect2, varscan2
- GRIA1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs1370479117, COSV53612219; called by muse, mutect2, varscan2
- GRM7 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.535); catalogued as COSV63153062; called by muse, mutect2, varscan2
- GRP | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV56879949; called by muse, mutect2, varscan2
- GSAP | c.1415C>A p.S472* | Nonsense Mutation (SNP) | VAF 41/131 reads (31%) | catalogued as rs1161841210, COSV99990266; called by muse, mutect2, varscan2
- GSTK1 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV64424481; called by muse, varscan2
- GTDC1 | c.462C>G p.S154R | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV53999436; called by muse, mutect2, varscan2
- GUCY1A1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs989003819, COSV56649597; called by muse, mutect2, varscan2
- H1-4 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1387610611, COSV56800081, COSV99175236; called by muse, mutect2, varscan2
- H2AC14 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV60797225; called by muse, mutect2, varscan2
- H2AC8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV55127301; called by muse, mutect2, varscan2
- H2BC4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as rs879122516, COSV58414927, COSV58416609, COSV58417570; called by muse, mutect2, varscan2
- H3C7 | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55099876, COSV55100372; called by muse, mutect2, varscan2
- H4C5 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs749157094, COSV63487075, COSV63487681; called by muse, mutect2, varscan2
- HAND2 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100854265, COSV64018546; called by muse, mutect2, varscan2
- HDAC8 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV65238574; called by muse, mutect2, varscan2
- HEATR5B | c.5392G>C p.D1798H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV51855227; called by muse, mutect2, varscan2
- HECTD4 | c.9055G>C p.E3019Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV66395109; called by muse, mutect2, varscan2
- HERC1 | c.10030G>C p.D3344H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV101496635; called by muse, mutect2, varscan2
- HHLA2 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV63318391; called by muse, mutect2, varscan2
- HIRA | c.2088C>G p.V696= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs749834610, COSV99600513; called by muse, mutect2
- HIVEP3 | c.6742G>A p.E2248K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs374566917, COSV56018449; called by muse, mutect2, varscan2
- HNRNPA1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.702); catalogued as COSV99267697; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1458877974, COSV54564298; called by muse, mutect2, varscan2
- HRNR | c.5935C>A p.P1979T | Missense Mutation (SNP) | VAF 90/878 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs754024699, COSV100913461, COSV64260156; called by muse, varscan2
- HS6ST2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs768825303, COSV63715287; called by muse, mutect2, varscan2
- HSP90B1 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV55356455; called by muse, mutect2, varscan2
- HSPA1L | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV65150451, COSV65150873, COSV65151044; called by muse, mutect2, varscan2
- HUWE1 | c.9875C>T p.A3292V | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53354182; called by muse, mutect2
- ICAM5 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV55748061; called by muse, mutect2, varscan2
- ID1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as COSV65888708; called by muse, varscan2
- ID1 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.044); catalogued as rs770706614, COSV65888720; called by muse, mutect2, varscan2
- IFNAR1 | c.1188G>T p.L396F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54253092; called by muse, mutect2, varscan2
- IGF2BP2 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV60488311, COSV99063379; called by muse, mutect2, varscan2
- IGHV3-72 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs369745775; called by muse, mutect2, varscan2
- IGSF22 | c.1296G>C p.E432D | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV60033507; called by muse, mutect2, varscan2
- IMP4 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV52091821, COSV52092211; called by muse, mutect2, varscan2
- IMPG2 | c.1421C>G p.S474C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs377032263; called by muse, mutect2, varscan2
- INTS4 | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1460696256, COSV71089830; called by muse, mutect2
- IQCJ-SCHIP1 | c.1113G>C p.Q371H (on ENST00000485419 / NM_001197113.1; = p.Q295H on NM_014575.3) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100539360, COSV61850139; called by muse, mutect2, varscan2
- IRS4 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.615); catalogued as rs776473962, COSV64534611; called by muse, mutect2, varscan2
- ITGA6 | c.811C>T p.P271S (on ENST00000442250; = p.P113S on NM_001316306.2) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51232811; called by muse, mutect2, varscan2
- ITGA7 | c.2418C>G p.F806L (on ENST00000555728; = p.F762L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV57697486; called by muse, mutect2, varscan2
- ITSN2 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 43/123 reads (35%) | catalogued as COSV100743708; called by muse, mutect2, varscan2
- KATNB1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65551497; called by muse, mutect2, varscan2
- KCNC3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV65388065; called by muse, mutect2, varscan2
- KCNK16 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.284); catalogued as rs1182057201, COSV100949228; called by muse, mutect2, varscan2
- KDR | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55769677; called by muse, mutect2, varscan2
- KIAA1328 | c.1389G>C p.K463N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs376667249, COSV54458709; called by muse, mutect2, varscan2
- KIAA1549L | c.3543G>A p.W1181* (on ENST00000321505; = p.W1478* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV55776930, COSV99683734; called by muse, mutect2, varscan2
- KIAA1614 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV62553142; called by muse, mutect2, varscan2
- KIAA1841 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV54374780, COSV54376461; called by muse, mutect2, varscan2
- KIDINS220 | c.4087C>T p.L1363F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV56755776; called by muse, mutect2, varscan2
- KIF15 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58162631; called by muse, mutect2, varscan2
- KIF18A | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54185040; called by muse, mutect2, varscan2
- KIF20B | c.2996C>T p.S999F (on ENST00000371728 / NM_001284259.2; = p.S959F on NM_016195.4) | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV53310665; called by muse, mutect2, varscan2
- KIF2B | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as COSV99275588; called by muse, mutect2, varscan2
- KIF7 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101067769; called by muse, mutect2, varscan2
- KIRREL1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100779962; called by muse, mutect2, varscan2
- KLF10 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99574805; called by muse, mutect2, varscan2
- KLK15 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.348); catalogued as COSV56827536; called by muse, mutect2, varscan2
- KNTC1 | c.4871C>G p.S1624W | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61081740, COSV61082253; called by muse, mutect2, varscan2
- KRTAP4-3 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs369554170; called by muse, varscan2
- LHB | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 58/98 reads (59%) | catalogued as rs1411902655, COSV55486522, COSV99669069; called by muse, mutect2, varscan2
- LILRA6 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as COSV54440005, COSV99556883; called by muse, mutect2, varscan2
- LRFN2 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1444702938, COSV100599926, COSV57830426; called by muse, mutect2, varscan2
- LRFN2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV57827271; called by muse, mutect2, varscan2
- LRP8 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60099788, COSV60101925; called by muse, mutect2, varscan2
- LRRC45 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1209942996, COSV100141857, COSV60711427; called by muse, mutect2, varscan2
- LRRC71 | c.1440C>T p.I480= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs1198814939, COSV59359002; called by muse, mutect2, varscan2
- LTBP1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1297197693, COSV100617368; called by muse, mutect2, varscan2
- LTBP3 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV57242184, COSV57243724; called by muse, mutect2, varscan2
- LUZP4 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV100904858; called by muse, mutect2, varscan2
- LY9 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV54431713, COSV54435638; called by muse, mutect2, varscan2
- LZTS1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs910745164, COSV56117519; called by muse, mutect2, varscan2
- MAGEE1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs781944261, COSV63909097; called by muse, mutect2
- MALT1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV61935561; called by muse, mutect2, varscan2
- MAP3K9 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67122058; called by muse, mutect2, varscan2
- MARS2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571781; called by muse, mutect2, varscan2
- MASTL | c.2627G>A p.G876E (on ENST00000375940 / NM_001372029.1; = p.G875E on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV60911534; called by muse, mutect2, varscan2
- MCM9 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs531682044, COSV60164648; called by muse, mutect2, varscan2
- MCPH1 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV100765905; called by muse, mutect2
- MDN1 | c.7793G>A p.R2598Q | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs149622123; called by muse, mutect2, varscan2
- MED13 | c.5624-1G>A p.X1875_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV67265064; called by muse, mutect2, varscan2
- MED13 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs568573606, COSV67265070; called by muse, mutect2, varscan2
- MFSD2B | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV57855393; called by muse, mutect2, varscan2
- MICAL3 | c.3226G>A p.V1076M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as COSV71588761; called by muse, mutect2, varscan2
- MIDEAS | c.3076G>C p.E1026Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV54096404; called by muse, mutect2, varscan2
- MIOS | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV60769540; called by muse, mutect2, varscan2
- MISP | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV53121351; called by muse, mutect2, varscan2
- MITF | c.794G>A p.G265E (on ENST00000448226 / NM_006722.3; = p.G159E on NM_000248.4) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV58833288; called by muse, mutect2, varscan2
- MLF2 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV99180096; called by muse, mutect2
- MMD2 | c.644G>C p.G215A (on ENST00000404774 / NM_001100600.2; = p.G191A on NM_198403.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68661119; called by muse, mutect2, varscan2
- MMP25 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV60680251; called by muse, mutect2, varscan2
- MPP7 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1440664645, COSV61734978; called by muse, mutect2, varscan2
- MRC2 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs770217464, COSV57641746; called by muse, mutect2, varscan2
- MROH7 | c.3744G>C p.L1248F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64887493; called by muse, mutect2, varscan2
- MS4A13 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1485016608, COSV100981175, COSV65445654, COSV65445864; called by muse, mutect2, varscan2
- MSH4 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV54206502; called by muse, mutect2, varscan2
- MSH4 | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54206524; called by muse, mutect2, varscan2
- MSH5 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs965034637, COSV65210386; called by muse, mutect2, varscan2
- MSI2 | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV52362499; called by muse, mutect2, varscan2
- MTA2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53470865; called by muse, mutect2, varscan2
- MTIF2 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV55052515; called by muse, mutect2, varscan2
- MUC21 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as COSV66221427; called by muse, mutect2, varscan2
- MUC6 | c.2899G>C p.D967H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70144868; called by muse, mutect2, varscan2
- MYCBP2 | c.11725G>C p.D3909H (on ENST00000357337; = p.D3947H on NM_015057.5) | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62028122; called by muse, mutect2, varscan2
- MYH10 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV52605147; called by muse, mutect2, varscan2
- MYLK | c.5629G>A p.D1877N | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60614790; called by muse, mutect2, varscan2
- MYO9B | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV101261303, COSV68280872; called by muse, mutect2, varscan2
- MYOM1 | c.3377C>A p.P1126Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55295516; called by muse, mutect2, varscan2
- NANP | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59160367; called by muse, mutect2, varscan2
- NAV1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1306076333, COSV55221095; called by muse, mutect2, varscan2
- NAV3 | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs1391530718, COSV57094360; called by muse, mutect2, varscan2
- NBPF3 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs1558473774, COSV100558864; called by muse, mutect2, varscan2
- NCAM2 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1470626957, COSV53087267, COSV99522375; called by muse, mutect2, varscan2
- NCOA7 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57657295, COSV57659560; called by muse, mutect2, varscan2
- NEB | c.19429C>T p.Q6477* | Nonsense Mutation (SNP) | VAF 52/165 reads (32%) | catalogued as COSV99424391; called by muse, mutect2, varscan2
- NEB | c.18211C>G p.H6071D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50806892, COSV51433715; called by muse, mutect2, varscan2
- NES | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1372053111, COSV63961731; called by muse, mutect2, varscan2
- NES | c.2602C>G p.Q868E | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV63961680, COSV63961736; called by muse, mutect2, varscan2
- NKX2-3 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60728939; called by muse, mutect2, varscan2
- NLRP2 | c.3061G>C p.D1021H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs747325012, COSV54757261; called by muse, mutect2, varscan2
- NME7 | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 33/139 reads (24%) | catalogued as COSV100891068; called by muse, mutect2, varscan2
- NOA1 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51737843, COSV51738005; called by muse, mutect2, varscan2
- NOC2L | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1003561399, COSV58988986, COSV58989573; called by muse, mutect2, varscan2
- NOVA2 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.766); catalogued as rs1303056978, COSV54355963; called by muse, varscan2
- NPIPB15 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.646); catalogued as rs748069611, COSV70437871; called by muse, mutect2, varscan2
- NR1D2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as rs1352385412, COSV56991577, COSV56992263; called by muse, mutect2, varscan2
- NR1H3 | c.1020C>G p.F340L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.894); catalogued as COSV60624183, COSV60626459; called by muse, mutect2, varscan2
- NR1H4 | c.193C>T p.P65S (on ENST00000551379 / NM_001206993.2; = p.P55S on NM_005123.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV51849605, COSV51856501; called by muse, mutect2, varscan2
- NRBP1 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV51994998; called by muse, mutect2, varscan2
- NRCAM | c.3769G>C p.D1257H (on ENST00000379028 / NM_001371124.1; = p.D1136H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61041936; called by muse, mutect2, varscan2
- NSD3 | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV57671538; called by muse, varscan2
- NSD3 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57620424; called by muse, mutect2, varscan2
- NUGGC | c.1035C>G p.F345L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as COSV58436665; called by muse, mutect2, varscan2
- NUP133 | c.3115G>T p.E1039* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as rs1222830880, COSV99773039; called by muse, mutect2, varscan2
- NUP133 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99773042; called by muse, mutect2, varscan2
- NUP43 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV61190552; called by muse, mutect2, varscan2
- NUSAP1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778856260, COSV52971959, COSV52972677; called by muse, mutect2
- OAS2 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1282763262, COSV60803337; called by muse, mutect2, varscan2
- OR14I1 | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV61200267; called by muse, mutect2, varscan2
- OR4K15 | c.874G>A p.D292N (on ENST00000305051; = p.D268N on NM_001005486.1) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV59302100; called by muse, mutect2, varscan2
- OR4X2 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.452); catalogued as COSV56584209; called by muse, mutect2, varscan2
- OR5A1 | c.62C>G p.T21R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV57377333; called by muse, mutect2, varscan2
- OR5A1 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV57377344; called by muse, mutect2, varscan2
- OR5A1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57377354; called by muse, mutect2, varscan2
- OR5AS1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57981209; called by muse, mutect2, varscan2
- OR5H6 | c.195C>G p.I65M (on ENST00000642105; = p.I49M on NM_001005479.2) | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67351773; called by muse, mutect2, varscan2
- OSBPL9 | c.1294C>G p.Q432E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV61872351; called by muse, mutect2, varscan2
- PARD3B | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as COSV62510422, COSV62512001, COSV62519020; called by muse, varscan2
- PARVB | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV100601388; called by muse, mutect2, varscan2
- PCBP1 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV57851411; called by muse, mutect2, varscan2
- PCCB | c.1152C>G p.F384L | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52446366; called by muse, mutect2, varscan2
- PCDH12 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.182); catalogued as COSV51522676, COSV51525295; called by muse, mutect2, varscan2
- PCDH15 | c.5350G>A p.E1784K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64709885; called by muse, mutect2, varscan2
- PCDHA2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 105/194 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65368770; called by muse, mutect2, varscan2
- PCDHA8 | c.1514C>G p.S505W | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs146745311, COSV65329056; called by muse, mutect2, varscan2
- PCDHGC5 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.174); catalogued as COSV52758037, COSV52758790; called by muse, varscan2
- PCNT | c.7075G>T p.E2359* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100855641; called by muse, mutect2, varscan2
- PDCD6 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV53779252; called by muse, mutect2, varscan2
- PDE11A | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV53700441; called by muse, mutect2, varscan2
- PDE12 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV60818324; called by muse, mutect2, varscan2
- PELI1 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV62730415; called by muse, mutect2, varscan2
- PHLPP2 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV62425537; called by muse, mutect2, varscan2
- PHLPP2 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV62425544; called by muse, mutect2, varscan2
- PIK3CB | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV56685948; called by muse, mutect2, varscan2
- PIM2 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.098); catalogued as COSV55945575; called by muse, mutect2, varscan2
- PKD2L1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV58397014; called by mutect2, varscan2
- PKHD1 | c.9370C>A p.H3124N | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM041062, COSV61885278; called by muse, mutect2
- PLA2G15 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV54723776; called by muse, mutect2, varscan2
- PLCG1 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV54820778; called by muse, mutect2, varscan2
- PLCG2 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.542); catalogued as COSV63872199; called by muse, mutect2, varscan2
- PLD3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52522708; called by mutect2, varscan2
- PLEKHH1 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV61285346; called by muse, mutect2, varscan2
- PMPCB | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV50786764; called by muse, mutect2
- PNCK | c.163G>T p.E55* (on ENST00000340888 / NM_001366975.1; = p.E138* on NM_001039582.3) | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100562358; called by muse, mutect2, varscan2
- PNMA2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV72908565; called by muse, mutect2, varscan2
- PNPT1 | c.2235G>C p.M745I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.194); catalogued as COSV53178545; called by muse, mutect2, varscan2
- POLR2B | c.90C>T p.I30= | Splice Region (SNP) | VAF 32/96 reads (33%) | catalogued as COSV100108092; called by muse, mutect2, varscan2
- POLR2B | c.2559G>C p.L853F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV58901525; called by muse, mutect2, varscan2
- POLR2H | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV56178206; called by muse, varscan2
- POLR2M | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV55211155; called by muse, mutect2
- PPFIA2 | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61041337; called by muse, mutect2
- PPHLN1 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56733437; called by muse, mutect2, varscan2
- PPP2R5B | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV51211008, COSV99376240; called by muse, mutect2, varscan2
- PPP2R5C | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58273508, COSV58276702; called by muse, mutect2, varscan2
- PRDX1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as rs765714807, COSV53114205; called by muse, mutect2, varscan2
- PRKAR2A | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55552980; called by muse, mutect2, varscan2
- PROSER2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53206731; called by muse, mutect2, varscan2
- PTPRB | c.5326C>G p.Q1776E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54246238; called by muse, mutect2, varscan2
- PYROXD1 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53710604; called by muse, mutect2, varscan2
- PZP | c.2718C>G p.I906M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54364516; called by muse, mutect2, varscan2
- QDPR | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV55549710, COSV99845858; called by muse, mutect2
- R3HCC1L | c.1854G>C p.E618D (on ENST00000612478 / NM_001256619.2; = p.E604D on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV54403093; called by muse, mutect2, varscan2
- RAD51C | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs28363311, CM120336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAI2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.381); catalogued as rs954913951, COSV58963877; called by muse, mutect2, varscan2
- RALY | c.793G>A p.E265K (on ENST00000246194 / NM_016732.3; = p.E249K on NM_007367.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV55782387; called by muse, mutect2, varscan2
- RASL10B | c.537C>A p.C179* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1299785651; called by muse, mutect2
- RBBP4 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65132898; called by muse, mutect2, varscan2
- RBM26 | c.2551C>T p.L851F (on ENST00000438737 / NM_001366735.2; = p.L824F on NM_022118.5) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104387251, COSV57390751; called by muse, mutect2, varscan2
- RCN2 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58031654; called by muse, mutect2, varscan2
- REV3L | c.5282C>G p.S1761C | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV100725078, COSV62620935; called by muse, mutect2, varscan2
- REV3L | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62620940; called by muse, mutect2, varscan2
- RGS3 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 77/132 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV58282713; called by muse, mutect2, varscan2
- RNF40 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV61215613; called by muse, mutect2, varscan2
- RORA | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV59536039; called by muse, mutect2, varscan2
- RPA4 | c.262A>T p.N88Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV61279251; called by muse, mutect2, varscan2
- RPGRIP1L | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50909952, COSV50912040; called by muse, mutect2, varscan2
- RPGRIP1L | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV50909975; called by muse, mutect2, varscan2
- RTN1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs373346838, COSV99956842; called by muse, varscan2
- RTP1 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV56618929; called by muse, mutect2, varscan2
- SAMHD1 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV53430798; called by muse, mutect2, varscan2
- SBNO1 | c.4044G>C p.L1348F (on ENST00000420886; = p.L1347F on NM_018183.5) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57343342; called by muse, mutect2, varscan2
- SCML2 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV52622971, COSV52623041; called by muse, mutect2, varscan2
- SCN9A | c.2489G>C p.G830A (on ENST00000303354; = p.G819A on NM_002977.3) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57615761, COSV57624220; called by muse, mutect2, varscan2
- SCUBE2 | c.2080G>T p.E694* (on ENST00000649792 / NM_001367977.2; = p.E539* on NM_001170690.2) | Nonsense Mutation (SNP) | VAF 51/114 reads (45%) | catalogued as COSV100496743; called by muse, mutect2, varscan2
- SDCBP | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50692057; called by muse, mutect2, varscan2
- SDHD | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as COSV100978945; called by muse, mutect2, varscan2
- SDK1 | c.6371C>G p.S2124* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101269505; called by muse, mutect2, varscan2
- SDK2 | c.5044G>T p.E1682* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs1284600293, COSV101167821; called by muse, mutect2, varscan2
- SDK2 | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs1164325638, COSV66190756; called by muse, mutect2, varscan2
- SEC62 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61261715; called by muse, mutect2, varscan2
- SENP7 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100053400; called by muse, mutect2, varscan2
- SEPTIN4 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57897559; called by muse, mutect2, varscan2
- SERHL2 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV59669552; called by muse, mutect2, varscan2
- SERPINC1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs776662899, COSV62928895; called by muse, mutect2, varscan2
- SERTAD2 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57640725; called by muse, mutect2, varscan2
- SESTD1 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58931872; called by muse, mutect2, varscan2
- SETD2 | c.5719G>C p.E1907Q | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV57442968; called by muse, mutect2, varscan2
- SETX | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141974509; called by muse, mutect2, varscan2
- SH2B2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782143454, COSV60826845; called by mutect2, varscan2
- SIN3A | c.3622C>G p.Q1208E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV51232104; called by muse, mutect2, varscan2
- SLC16A2 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52086235; called by muse, mutect2, varscan2
- SLC22A25 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.088); catalogued as rs1328673179, COSV60594644, COSV60597257; called by muse, mutect2, varscan2
- SLC25A14 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54419026; called by muse, mutect2, varscan2
- SLC2A11 | c.1189G>A p.E397K (on ENST00000345044 / NM_001024938.4; = p.E404K on NM_030807.5) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55392591; called by muse, mutect2
- SLC32A1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54147438; called by muse, mutect2, varscan2
- SLC38A11 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV58054781, COSV58056208; called by muse, mutect2, varscan2
- SLC41A1 | c.1145G>C p.G382A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65650939; called by muse, mutect2, varscan2
- SLC9A2 | c.2060C>G p.S687C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV52134081; called by muse, mutect2, varscan2
- SLC9A4 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV54836297; called by muse, mutect2, varscan2
- SMC3 | c.2575C>G p.L859V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV62421077; called by muse, mutect2, varscan2
- SMG5 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV62436347; called by muse, mutect2, varscan2
- SNRPB | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV60016039, COSV60016456; called by muse, mutect2, varscan2
- SNX7 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV60269946; called by muse, mutect2, varscan2
- SPATA32 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100077485; called by muse, mutect2, varscan2
- SPATA6 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100893063, COSV64057598; called by muse, mutect2, varscan2
- SPOPL | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV54514615; called by muse, mutect2, varscan2
- SPTB | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs371440362, COSV67631103; called by muse, mutect2, varscan2
- SRP72 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV61378405; called by muse, mutect2, varscan2
- SRPRB | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs954669680, COSV101524157, COSV71749135; called by muse, mutect2, varscan2
- SRRT | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52342448; called by muse, mutect2, varscan2
- STRADB | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52044745; called by muse, mutect2, varscan2
- STRIP1 | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100874088, COSV63930806; called by muse, mutect2, varscan2
- STYXL2 | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 125/343 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54807241; called by muse, mutect2, varscan2
- SUCO | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1194601369, COSV55267899; called by muse, mutect2, varscan2
- SYNDIG1 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65237171; called by muse, mutect2, varscan2
- SYNPO2 | c.2868G>C p.K956N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61113842; called by muse, mutect2, varscan2
- SYTL3 | c.1423C>G p.Q475E (on ENST00000611299 / NM_001242394.1; = p.Q407E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51912138; called by muse, mutect2, varscan2
- TAS2R39 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs766695438, COSV71470930; called by muse, mutect2, varscan2
- TATDN2 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV55052736; called by muse, mutect2, varscan2
- TBC1D32 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51547416; called by muse, varscan2
- TBX2 | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV53599907; called by muse, mutect2, varscan2
- TCEA2 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV58658454; called by muse, mutect2, varscan2
- TCHH | c.3390G>C p.K1130N | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as COSV64276124; called by muse, mutect2, varscan2
- TCHH | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as COSV64273811; called by muse, mutect2, varscan2
- TCOF1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs770606504, COSV60350772; called by muse, mutect2, varscan2
- TCP11L2 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV54431176; called by muse, mutect2, varscan2
- TDRD1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1274746093, COSV52592839; called by muse, mutect2, varscan2
- TET1 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65382889; called by muse, mutect2, varscan2
- TLN1 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59209349; called by muse, mutect2, varscan2
- TMTC3 | c.1016G>C p.R339T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV57124896, COSV57126302; called by muse, mutect2
- TNFAIP3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV52799748; called by muse, mutect2, varscan2
- TNRC6C | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100050132; called by muse, mutect2, varscan2
- TNS1 | c.3535C>T p.Q1179* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV50721124, COSV50744264; called by muse, mutect2, varscan2
- TONSL | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV68048784; called by muse, mutect2, varscan2
- TOX2 | c.358C>G p.Q120E (on ENST00000358131 / NM_001098798.2; = p.Q69E on NM_032883.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV57882917, COSV57889841; called by muse, mutect2, varscan2
- TP53BP1 | c.2027G>C p.G676A | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as COSV55504434; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV64853354; called by muse, mutect2, varscan2
- TRAPPC8 | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV51974107, COSV51977876; called by muse, mutect2, varscan2
- TRIM61 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1260661361, COSV100256079; called by mutect2, varscan2
- TRIO | c.4537G>C p.E1513Q | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60087732; called by muse, mutect2, varscan2
- TRIP13 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs149813610; called by muse, mutect2, varscan2
- TRPM1 | c.3664G>C p.E1222Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs267604151, COSV56630519, COSV56637577, COSV99856215; called by muse, mutect2, varscan2
- TSC22D3 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV59778497; called by muse, mutect2, varscan2
- TSPYL2 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1169578163, COSV64921301; called by muse, mutect2, varscan2
- TSSK3 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61982538; called by muse, mutect2, varscan2
- TTI2 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100659746; called by muse, mutect2, varscan2
- TTLL12 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53355989; called by muse, mutect2, varscan2
- TTLL7 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1293261975, COSV53086222; called by muse, mutect2, varscan2
- TTN | c.78786G>C p.Q26262H (on ENST00000591111; = p.Q18838H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | PolyPhen possibly damaging (0.768); catalogued as COSV60177573; called by muse, mutect2, varscan2
- TTN | c.78396G>C p.L26132F (on ENST00000591111; = p.L18708F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | PolyPhen benign (0.037); catalogued as rs767568495, COSV60177601; called by muse, mutect2
- TTN | c.41179G>A p.E13727K (on ENST00000591111; = p.E6303K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | PolyPhen probably damaging (0.994); catalogued as COSV60177633; called by muse, mutect2, varscan2
- UBQLN4 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV64145580; called by muse, varscan2
- UBXN2B | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV68309342; called by muse, mutect2
- UNC5C | c.1875G>C p.K625N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV71661041; called by muse, mutect2, varscan2
- UNC5C | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as COSV71658951, COSV71661042; called by muse, mutect2, varscan2
- UNCX | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572503180, COSV60333397; called by muse, mutect2, varscan2
- USF3 | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV57074870; called by muse, mutect2, varscan2
- USP34 | c.8758G>C p.D2920H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV68403353; called by muse, mutect2, varscan2
- USP34 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV68403359; called by muse, mutect2, varscan2
- USP39 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs756071519, COSV100083900; called by muse, varscan2
- USP40 | c.2847G>C p.E949D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as COSV52483861; called by muse, mutect2, varscan2
- USP45 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV59681497; called by muse, mutect2, varscan2
- USP54 | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as rs748842872, COSV60444689; called by muse, mutect2, varscan2
- USP9X | c.6861G>C p.K2287N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61071704; called by muse, mutect2, varscan2
- VAT1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV55896616; called by muse, mutect2, varscan2
- VAV2 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1177442941, COSV64083802, COSV64083968; called by muse, mutect2, varscan2
- VCPIP1 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV60048923; called by muse, mutect2, varscan2
- VPS28 | c.665G>C p.*222Sext*? | Nonstop Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99465702; called by mutect2, varscan2
- VWA2 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs891878881, COSV53908561; called by muse, mutect2, varscan2
- VWCE | c.1965G>A p.L655= | Splice Region (SNP) | VAF 13/50 reads (26%) | catalogued as COSV57113617; called by muse, varscan2
- VWCE | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs746653589, COSV57112161; called by muse, varscan2
- VWCE | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV57113631; called by muse, mutect2, varscan2
- WWP2 | c.273G>C p.L91F | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs1392761618, COSV63126017; called by muse, mutect2, varscan2
- XDH | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65149114, COSV65149907; called by muse, varscan2
- XIRP1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775823156, COSV61139534; called by muse, mutect2, varscan2
- XIRP1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61139541; called by muse, mutect2, varscan2
- XIRP2 | c.9724G>A p.E3242K (on ENST00000628543; = p.E3417K on NM_152381.6) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV54714671; called by muse, mutect2, varscan2
- XRCC4 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs780603098, COSV56541173; called by muse, mutect2, varscan2
- XYLB | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99264263; called by muse, mutect2, varscan2
- YARS1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs776582429, COSV65114506; called by muse, varscan2
- YY2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100810784; called by muse, mutect2, varscan2
- ZBTB24 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV57782721; called by muse, mutect2, varscan2
- ZC3H13 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54450643; called by muse, mutect2, varscan2
- ZC3H7B | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV60963171; called by muse, mutect2, varscan2
- ZC3H7B | c.2382G>C p.K794N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs1291801798, COSV60963181; called by muse, mutect2, varscan2
- ZC3HAV1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1277529416, COSV99648721; called by muse, mutect2
- ZCCHC9 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV54176617; called by muse, mutect2, varscan2
- ZDBF2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65627798; called by muse, mutect2, varscan2
- ZFAND6 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV55712771; called by muse, mutect2
- ZKSCAN3 | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99356987; called by muse, mutect2, varscan2
- ZNF106 | c.5249G>A p.G1750E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398034958, COSV55518743; called by muse, mutect2, varscan2
- ZNF107 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as rs761310625, COSV61329990; called by muse, mutect2, varscan2
- ZNF236 | c.4634C>T p.S1545F | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767498736, COSV53492132; called by muse, mutect2, varscan2
- ZNF317 | c.1234C>G p.H412D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99927181; called by muse, mutect2
- ZNF415 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs765702783, COSV54702893; called by muse, mutect2, varscan2
- ZNF432 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1291398954, COSV55417462; called by muse, mutect2, varscan2
- ZNF502 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV56074200; called by muse, mutect2, varscan2
- ZNF572 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV60001922; called by muse, mutect2, varscan2
- ZNF572 | c.1574C>G p.S525* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV60002910; called by muse, mutect2, varscan2
- ZNF609 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.814); catalogued as COSV58585902; called by muse, mutect2, varscan2
- ZNF648 | c.1344C>G p.F448L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV100374647; called by muse, mutect2
- ZNF654 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as rs1253470682, COSV58806506; called by muse, mutect2, varscan2
- ZNF75D | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV66132659; called by muse, mutect2, varscan2
- ZNF804A | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV56457854; called by muse, mutect2, varscan2
- ZNF804B | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60838131; called by muse, mutect2, varscan2
- ZNF81 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs782814815, COSV58577148; called by muse, mutect2, varscan2
- ZSCAN4 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 99/144 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV56593838; called by muse, mutect2, varscan2
- ACACA | c.6652C>T p.Q2218* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | called by muse, mutect2, varscan2
- CCL3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPDYE5 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- A2M | c.117C>G p.L39= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV59389288; called by muse, mutect2, varscan2
- AAMP | c.426C>T p.F142= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1316842126, COSV50308329; called by muse, mutect2, varscan2
- AATK | c.2760C>T p.F920= (on ENST00000326724 / NM_001080395.3; = p.F817= on NM_004920.2) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58369520, COSV58373991; called by muse, mutect2, varscan2
- ABL2 | c.1030C>T p.L344= (on ENST00000502732 / NM_007314.4; = p.L329= on NM_005158.5) | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV61017244; called by muse, mutect2, varscan2
- ACO1 | c.165G>C p.V55= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV59381643; called by muse, mutect2, varscan2
- ADGRL4 | c.1353C>T p.F451= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs1452989557, COSV66062953; called by muse, mutect2, varscan2
- AGO4 | c.1905C>G p.L635= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1440943547, COSV64617750; called by muse, mutect2, varscan2
- AIP | c.24C>G p.L8= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54160371; called by muse, mutect2, varscan2
- AKAP13 | c.3702C>G p.V1234= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV63463645; called by muse, mutect2, varscan2
- AKAP13 | c.6720G>A p.L2240= (on ENST00000394518 / NM_007200.5; = p.L2244= on NM_006738.6) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63463653; called by muse, mutect2, varscan2
- AMD1 | c.484C>T p.L162= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV64387753; called by muse, mutect2, varscan2
- APOB | c.2454G>A p.R818= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51942723; called by muse, mutect2, varscan2
- APOB | c.2277G>A p.E759= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV51942728; called by muse, mutect2, varscan2
- ARF1 | c.264G>A p.L88= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as rs1255976085, COSV55255269; called by muse, mutect2, varscan2
- ARHGAP31 | c.1539G>A p.P513= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs753289468, COSV51791814; called by muse, mutect2, varscan2
- ARID1B | c.3135G>C p.T1045= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51669588, COSV99271562; called by muse, mutect2, varscan2
- ASCC2 | c.2094C>T p.A698= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV57074911; called by muse, mutect2, varscan2
- ASTN1 | c.309C>T p.I103= | Silent (SNP) | VAF 21/224 reads (9%) | catalogued as COSV56061591; called by muse, mutect2
- ATF6B | c.522C>G p.V174= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64352175; called by muse, mutect2, varscan2
- ATRAID | c.549C>G p.V183= (on ENST00000611786; = p.V70= on NM_016085.5) | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as COSV53028894; called by muse, mutect2, varscan2
- BPHL | c.183C>T p.H61= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs754914068, COSV66744052; called by muse, mutect2, varscan2
- BRAT1 | c.1752G>A p.E584= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV61396196; called by muse, mutect2, varscan2
- C15orf48 | c.21G>C p.L7= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV60223522; called by muse, mutect2, varscan2
- C1S | c.810C>T p.I270= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV61071394; called by muse, mutect2, varscan2
- CALR | c.621G>A p.K207= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs1408057401, COSV100331131, COSV57130242; called by muse, mutect2, varscan2
- CAMTA1 | c.3006G>C p.A1002= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV57912204, COSV57930402; called by muse, mutect2, varscan2
- CCDC27 | c.606G>A p.K202= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs1324498847, COSV53901607; called by muse, mutect2, varscan2
- CD101 | c.2892C>T p.F964= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs751035877, COSV56719126; called by muse, mutect2, varscan2
- CD1E | c.516C>G p.L172= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV63771867; called by muse, mutect2, varscan2
- CDKN1A | c.90G>A p.L30= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55190030; called by muse, varscan2
- CDYL2 | c.501G>A p.E167= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV73647743; called by muse, mutect2
- CEMIP | c.1113C>G p.L371= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV54995964; called by muse, mutect2, varscan2
- CEP350 | c.912G>A p.Q304= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV62486030; called by muse, mutect2, varscan2
- CEP85 | c.1011G>A p.L337= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV53330831; called by muse, mutect2, varscan2
- CNGA1 | c.1347C>G p.V449= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as COSV62055257; called by muse, mutect2, varscan2
- CNTN2 | c.786C>T p.F262= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs369368742; called by muse, mutect2, varscan2
- CNTNAP4 | c.2352C>G p.L784= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1332771081, COSV56689914; called by muse, mutect2, varscan2
- COL12A1 | c.891C>T p.F297= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV59400468; called by muse, mutect2, varscan2
- COL4A1 | c.2847G>A p.Q949= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV65428198; called by muse, mutect2, varscan2
- CPSF2 | c.445C>T p.L149= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs768832098, COSV54099201; called by muse, mutect2, varscan2
- CR1 | c.4023C>A p.P1341= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV65460009; called by muse, mutect2, varscan2
- CRB2 | c.2316C>T p.L772= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs142240363, COSV63504236; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTU1 | c.501C>T p.I167= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs776191804, COSV70292574; called by muse, varscan2
- CUL5 | c.231G>A p.Q77= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1204907401, COSV67609473; called by muse, mutect2, varscan2
- CYP4F8 | c.339C>T p.T113= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs769338147, COSV100358145; called by muse, varscan2
- DCAF12L1 | c.165G>C p.L55= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV64422202; called by muse, mutect2, varscan2
- DHX8 | c.2187C>T p.F729= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV52254757; called by muse, mutect2, varscan2
- DLC1 | c.3975C>T p.L1325= (on ENST00000276297 / NM_001348081.2; = p.L888= on NM_006094.5) | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV52313859; called by muse, mutect2, varscan2
- DNAH9 | c.11508G>A p.E3836= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV52359918; called by muse, mutect2, varscan2
- DNAI1 | c.1896C>G p.L632= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV54279951, COSV54282526; called by muse, mutect2, varscan2
- DNAJC11 | c.90G>T p.L30= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1322144444, COSV53788345; called by muse, mutect2, varscan2
- DOCK8 | c.36C>T p.F12= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV66688299; called by muse, varscan2
- DOCK8 | c.5310C>G p.L1770= | Silent (SNP) | VAF 54/80 reads (68%) | catalogued as rs1347537082, COSV66621668; called by muse, mutect2, varscan2
- DST | c.19551C>T p.L6517= (on ENST00000361203 / NM_001374722.1; = p.L4214= on NM_015548.5) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs373540758, COSV99750106; called by muse, mutect2, varscan2
- ERO1B | c.978C>T p.V326= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs777497495, COSV51596228; called by muse, mutect2, varscan2
- ESRRB | c.1203G>A p.Q401= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV55063713; called by muse, mutect2, varscan2
- EVI2B | c.462G>A p.Q154= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV58364518; called by muse, mutect2, varscan2
- FASTKD5 | c.240C>T p.F80= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV53907300; called by muse, mutect2, varscan2
- FBXL18 | c.1581C>T p.I527= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs577039942, COSV66107739; called by muse, varscan2
- FBXL18 | c.1518C>T p.I506= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV66107743; called by muse, varscan2
- FOXO3 | c.1188C>T p.L396= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59629446; called by muse, varscan2
- FOXO3 | c.1587C>T p.V529= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs767271331, COSV59629464; called by muse, mutect2, varscan2
- FOXP4 | c.855C>G p.L285= (on ENST00000307972 / NM_001012426.1; = p.L284= on NM_138457.3) | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV57221453; called by muse, mutect2, varscan2
- GALE | c.165G>A p.L55= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52526599; called by muse, mutect2, varscan2
- GLI3 | c.837C>T p.F279= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV67891212; called by muse, mutect2, varscan2
- GPR157 | c.282C>T p.F94= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV66234012; called by muse, mutect2, varscan2
- H1-4 | c.567G>A p.A189= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1397059282, COSV56800282, COSV56801664, COSV56803584; called by muse, mutect2, varscan2
- HADHA | c.1128C>T p.I376= | Silent (SNP) | VAF 94/328 reads (29%) | catalogued as rs765101895, COSV101024242, COSV66106592; called by muse, mutect2, varscan2
- HSD17B1 | c.508C>T p.L170= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99864819; called by muse, mutect2, varscan2
- HSPH1 | c.399C>G p.L133= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs111995920, COSV60712330; called by muse, mutect2, varscan2
- IGF2BP3 | c.153C>G p.L51= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs371773798; called by muse, mutect2
- IL12RB1 | c.1041C>T p.I347= | Silent (SNP) | VAF 61/85 reads (72%) | catalogued as COSV59098104; called by muse, mutect2, varscan2
- ILDR2 | c.1203C>T p.F401= | Silent (SNP) | VAF 35/368 reads (10%) | catalogued as COSV54832920; called by muse, mutect2
- IPCEF1 | c.495G>A p.E165= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV54546684; called by muse, mutect2, varscan2
- IQSEC3 | c.1027C>T p.L343= (on ENST00000538872 / NM_001170738.2; = p.L40= on NM_015232.1) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58283931; called by muse, mutect2
- KCNAB1 | c.48G>A p.E16= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as COSV67488238; called by muse, mutect2, varscan2
- KCNH1 | c.669C>T p.I223= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV55082023; called by muse, mutect2, varscan2
- KEL | c.1791C>G p.L597= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV62336329; called by muse, mutect2, varscan2
- KIF18A | c.510C>G p.L170= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV54185032; called by muse, mutect2, varscan2
- KLF5 | c.621C>T p.F207= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV66614886; called by muse, mutect2, varscan2
- LAMA3 | c.816C>T p.L272= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs374688140; called by muse, mutect2, varscan2
- LAMA5 | c.10401C>G p.L3467= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1283059858, COSV53364647; called by muse, mutect2, varscan2
- LILRB5 | c.39G>C p.L13= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV60259424; called by muse, mutect2, varscan2
- LIN52 | c.213C>A p.L71= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs777197282, COSV73465935; called by muse, mutect2, varscan2
- LRP1 | c.11511C>G p.L3837= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV54517438; called by muse, mutect2, varscan2
- LRP8 | c.2076G>C p.L692= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV60099777; called by muse, mutect2, varscan2
- LUC7L | c.576C>A p.V192= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV53459299; called by muse, mutect2, varscan2
- MAN1A1 | c.1431C>T p.F477= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1373838804, COSV63788207; called by muse, mutect2
- MAP3K9 | c.1530G>A p.L510= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV67122053; called by muse, mutect2, varscan2
- MAPK3 | c.1038C>T p.F346= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53774837; called by muse, mutect2, varscan2
- MSN | c.1716C>T p.D572= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs756544101, COSV64303827, COSV64304251; called by muse, mutect2, varscan2
- MYBPC2 | c.2079C>T p.F693= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV63097422; called by muse, mutect2, varscan2
- NBEA | c.8625G>A p.Q2875= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100081406; called by muse, mutect2, varscan2
- NDUFAF5 | c.441C>T p.F147= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1427137472, COSV65247312; called by muse, mutect2, varscan2
- NEB | c.12057C>T p.Y4019= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs768508081, COSV51433744; called by muse, mutect2
- NKAPD1 | c.30C>G p.L10= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV54775888; called by muse, mutect2, varscan2
- NLE1 | c.138C>T p.L46= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100681018; called by muse, mutect2
- NR1I3 | c.339G>A p.L113= | Silent (SNP) | VAF 24/269 reads (9%) | catalogued as COSV63468649; called by muse, mutect2
- NUDT16L1 | c.597G>A p.Q199= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs367705497; called by muse, mutect2, varscan2
- NUP214 | c.2484G>C p.V828= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV63911047; called by muse, mutect2, varscan2
- OCA2 | c.303G>A p.L101= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV62350983; called by muse, mutect2, varscan2
- OR2T6 | c.891G>C p.V297= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV63216692; called by muse, mutect2, varscan2
- OXCT1 | c.1203G>C p.A401= | Silent (SNP) | VAF 62/248 reads (25%) | catalogued as COSV52171569; called by muse, mutect2, varscan2
- PAX2 | c.915G>C p.S305= (on ENST00000428433 / NM_003987.5; = p.S282= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs777494044, COSV62291242, COSV62291950; called by muse, mutect2, varscan2
- PCDH11X | c.561C>T p.L187= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs1382233087, COSV100014575, COSV53509124; called by muse, mutect2, varscan2
- PCDHB2 | c.660G>C p.G220= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52032748, COSV52034708; called by muse, mutect2, varscan2
- PCDHGC5 | c.2109C>G p.L703= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV52758049; called by muse, varscan2
- PKHD1 | c.6405C>G p.L2135= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV61885289; called by muse, mutect2, varscan2
- PLIN4 | c.1740G>A p.L580= (on ENST00000301286; = p.L595= on NM_001367868.2) | Silent (SNP) | VAF 175/281 reads (62%) | catalogued as COSV56694309; called by muse, mutect2, varscan2
- PLK3 | c.450C>T p.I150= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59500331; called by muse, mutect2, varscan2
- PNPLA5 | c.585C>T p.I195= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV53375405; called by muse, mutect2, varscan2
- PPFIBP2 | c.1353G>A p.T451= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1382748964, COSV55079289; called by muse, mutect2, varscan2
- PPL | c.1173C>G p.L391= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV62048564; called by muse, mutect2, varscan2
- PPP1R26 | c.1347C>A p.L449= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as rs765339248, COSV63356307; called by muse, mutect2, varscan2
- PPP2R3B | c.1104G>A p.K368= | Silent (SNP) | VAF 45/250 reads (18%) | catalogued as rs1355535830, COSV66813843; called by muse, mutect2, varscan2
- PPP2R3B | c.954C>T p.V318= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs752262668, COSV66813851; called by muse, mutect2, varscan2
- PRAMEF15 | c.717C>G p.L239= | Silent (SNP) | VAF 70/355 reads (20%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.975G>C p.L325= | Silent (SNP) | VAF 138/369 reads (37%) | called by muse, mutect2, varscan2
- PRRT2 | c.987C>A p.I329= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs368411419, COSV54884812; called by muse, mutect2, varscan2
- PTPRR | c.705C>G p.L235= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV51738086; called by muse, mutect2, varscan2
- PUM2 | c.798G>A p.Q266= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1282809764, COSV57583129; called by muse, mutect2, varscan2
- PUSL1 | c.768G>A p.T256= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as rs747362903, COSV60089364; called by muse, mutect2, varscan2
- PWWP2A | c.1614G>A p.L538= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs1355087963, COSV101506898; called by muse, mutect2, varscan2
- R3HDM1 | c.6G>A p.R2= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1201500075, COSV51527971; called by muse, mutect2, varscan2
- RELB | c.1362C>T p.F454= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as rs1188982094, COSV55511489; called by muse, varscan2
- RELB | c.1494C>G p.L498= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV55511497; called by muse, varscan2
- ROGDI | c.801C>G p.L267= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs752844190, COSV59022033; called by muse, mutect2, varscan2
- RRM1 | c.39C>T p.V13= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56165028; called by muse, mutect2, varscan2
- RRP1B | c.2178G>C p.L726= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV61479532; called by muse, mutect2
- RSRC1 | c.36C>T p.S12= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV55833147; called by muse, mutect2, varscan2
- RYR3 | c.4677C>T p.Y1559= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs756679547, COSV66799418, COSV66812541; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCARA3 | c.183C>T p.F61= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV57270809; called by muse, mutect2, varscan2
- SCNN1A | c.1626C>T p.V542= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV57436444; called by muse, mutect2, varscan2
- SEMA3G | c.687C>T p.A229= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs368237957; called by muse, mutect2, varscan2
- SEMA4B | c.1842C>G p.L614= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV60174562; called by muse, mutect2, varscan2
- SEMA5A | c.534G>A p.E178= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs779196248, COSV66799035; called by muse, mutect2, varscan2
- SEPTIN3 | c.660C>T p.F220= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV52173114; called by muse, mutect2, varscan2
- SH3KBP1 | c.1653C>A p.P551= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV65648262, COSV65648932; called by muse, mutect2, varscan2
- SHROOM2 | c.4716C>T p.L1572= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1409894325, COSV66608464; called by muse, mutect2
- SHROOM3 | c.5553C>G p.L1851= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV56033746; called by muse, mutect2, varscan2
- SHTN1 | c.1563G>A p.L521= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV53379443, COSV99599039; called by muse, mutect2
- SIN3B | c.3180C>G p.L1060= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99931815; called by muse, mutect2
- SLC13A2 | c.174C>T p.V58= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58996562; called by muse, mutect2, varscan2
- SLC25A24 | c.345C>T p.L115= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs908998129, COSV51448828; called by muse, mutect2, varscan2
- SLC2A11 | c.1041G>C p.L347= (on ENST00000345044 / NM_001024938.4; = p.L354= on NM_030807.5) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55392569; called by muse, mutect2, varscan2
- SLC47A1 | c.591C>T p.V197= | Silent (SNP) | VAF 71/165 reads (43%) | catalogued as COSV54502441; called by muse, mutect2, varscan2
- SPATA32 | c.447C>T p.I149= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV59304281; called by muse, mutect2, varscan2
- SPTLC3 | c.1587G>A p.L529= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV65464173; called by muse, mutect2, varscan2
- ST8SIA1 | c.120C>A p.L40= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs1464182813, COSV53956277; called by muse, mutect2, varscan2
- STRA8 | c.870C>T p.I290= (on ENST00000275764; = p.I268= on NM_182489.2) | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV51962233; called by muse, mutect2, varscan2
- SUPT20H | c.954C>T p.I318= (on ENST00000350612 / NM_001014286.3; = p.I319= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1307219148, COSV62247366, COSV62248658; called by muse, mutect2, varscan2
- SUSD4 | c.747G>A p.V249= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV59554429; called by muse, mutect2, varscan2
- SYNGR1 | c.240C>T p.L80= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1474403843, COSV53368734; called by muse, mutect2, varscan2
- TAAR1 | c.105G>A p.L35= | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV51588996; called by muse, mutect2, varscan2
- TAF1 | c.2238G>C p.R746= (on ENST00000373790 / NM_138923.4; = p.R767= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV52118389; called by muse, mutect2, varscan2
- TBC1D32 | c.3738G>A p.L1246= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV51547406; called by muse, mutect2, varscan2
- TBCD | c.3147C>T p.H1049= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs553172184, COSV62803594; called by muse, mutect2, varscan2
- TCHH | c.2832G>C p.L944= | Silent (SNP) | VAF 105/320 reads (33%) | catalogued as COSV64276127, COSV64276830; called by muse, mutect2, varscan2
- TCHH | c.1092G>C p.L364= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV64276131; called by muse, varscan2
- TKFC | c.708G>A p.E236= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV67523844; called by muse, mutect2, varscan2
- TMEM132B | c.792C>A p.V264= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV54759605; called by muse, mutect2, varscan2
- TMPRSS6 | c.894C>T p.I298= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV60980760; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.492C>T p.F164= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV64423430; called by muse, mutect2, varscan2
- TNRC18 | c.2217C>T p.L739= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs373724208; called by muse, mutect2, varscan2
- TRIL | c.1368C>G p.L456= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV59867485; called by muse, mutect2, varscan2
- TRIM50 | c.288C>G p.L96= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV52719717; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- UPF1 | c.918C>T p.F306= | Silent (SNP) | VAF 54/82 reads (66%) | catalogued as rs771987109, COSV53198536; called by muse, varscan2
- VIRMA | c.3063G>C p.L1021= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV52587728; called by muse, mutect2, varscan2
- WDR33 | c.453C>T p.F151= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV59252090; called by muse, mutect2, varscan2
- WDR49 | c.922C>T p.L308= (on ENST00000308378 / NM_001366158.1; = p.L649= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV57712329; called by muse, mutect2, varscan2
- XPC | c.633C>G p.L211= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53206132; called by muse, mutect2, varscan2
- YAE1 | c.447G>A p.E149= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV56233303; called by muse, mutect2, varscan2
- ZAN | c.1011G>C p.V337= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV61811578; called by muse, mutect2, varscan2
- ZC3H4 | c.1287C>T p.I429= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV53410859, COSV53414600; called by muse, mutect2, varscan2
33 further variants in this file (0 protein-altering or splice-affecting, 11 silent, 22 other) are not listed here.
